Gene-level copy-number profile of tumor specimen ALCH-B2LX-TTP1-A from ALCHEMIST case ALCH-B2LX, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 80.7 years (29,471 days).
Specimen ALCH-B2LX-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e7e55795-d1d6-4cc5-8562-243a750f34f8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B2LX-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,253 have no estimate.
https://portal.gdc.cancer.gov/files/46ed1e53-e9ce-4799-8506-9add2f6eca62

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 162; copy number 2: 53,483; copy number 3: 4,167; copy number 4: 533; copy number 5: 20; copy number 6: 1; copy number 7: 4.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 25 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:11,869–31,109, 5 genes, copy number 5: DDX11L1, WASH7P, MIR6859-1, MIR1302-2HG, MIR1302-2.
- chr8:114,791,653–115,809,673, 3 genes, copy number 5: CARS1P2, TRPS1, AF178030.1.
- chr16:29,425,800–29,447,026, 1 gene, copy number 5: SMG1P6.
- chr16:29,443,056–29,482,591, 10 genes, copy number 5–7: BOLA2, BOLA2-SMG1P6, AC133555.4, SLX1B, SLX1B-SULT1A4, SULT1A4, AC133555.3, AC133555.5, AC133555.2, AC133555.1.
- chr19:1,228,287–1,238,027, 1 gene, copy number 6 (within-gene range 2–6): CBARP.
- chr21:44,107,373–44,210,114, 5 genes, copy number 5–7 (within-gene range 3–7): PWP2, GATD3A, LINC01678, AP001056.2, AP001056.1.

Autosomal genes at a single copy (total copy number 1): 160. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
